Somatic mutation profile of tumor specimen TCGA-DA-A95Z-06A (aliquot TCGA-DA-A95Z-06A-11D-A372-08) from TCGA case TCGA-DA-A95Z, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 87.2 years (31,837 days).
Specimen TCGA-DA-A95Z-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5be6648-c4a3-4196-b280-6bb99fd766bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A95Z-10A (Blood Derived Normal), aliquot TCGA-DA-A95Z-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3522249c-8219-46dc-b269-882d08f0b103

The open-access MAF lists 2,315 somatic variants for this specimen: 1,545 protein-altering or splice-affecting, 715 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,382, Silent 715, Nonsense Mutation 100, Splice Site 22, Splice Region 22, Intron 21, RNA 19, Frame Shift Del 14, 5'Flank 6, 3'Flank 4, 3'UTR 3, Translation Start Site 2.

Variants (750 of 2,315; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>A p.G506E (on ENST00000288602 / NM_001374244.1; = p.G466E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DDC | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs142110773, CM151311; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGR2 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs751448371, COSV54346083, COSV54347067; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IL7R | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 36/59 reads (61%) | hotspot (GDC flag); catalogued as rs201559094, CM045175, COSV57405649; called by muse, mutect2, varscan2
- NF1 | c.2266C>T p.Q756* | Nonsense Mutation (SNP) | VAF 33/67 reads (49%) | catalogued as rs1567847905, CM1110584, COSV62191872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.6921G>A p.K2307= (on ENST00000358273 / NM_001042492.3; = p.K2286= on NM_000267.3) | Splice Region (SNP) | VAF 29/122 reads (24%) | catalogued as rs1057523533, CS001443, COSV62193216; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PAK5 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 113/197 reads (57%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs769939031, COSV62021293; called by muse, mutect2, varscan2
- SLC27A5 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202081924, COSV54017957; called by muse, mutect2, varscan2
- A2ML1 | c.4189G>A p.G1397R | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.216); catalogued as COSV100228472; called by muse, mutect2, varscan2
- AASS | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as rs759258946, COSV100741645; called by muse, mutect2, varscan2
- ABCA12 | c.5309C>T p.S1770F (on ENST00000272895 / NM_173076.3; = p.S1452F on NM_015657.3) | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV99788106; called by muse, mutect2, varscan2
- ABCA12 | c.4831G>A p.D1611N (on ENST00000272895 / NM_173076.3; = p.D1293N on NM_015657.3) | Missense Mutation (SNP) | VAF 74/111 reads (67%) | SIFT tolerated (0.27); PolyPhen benign (0.405); catalogued as rs775054797, COSV55959959; called by muse, mutect2, varscan2
- ABCA12 | c.1027G>A p.G343R (on ENST00000272895 / NM_173076.3; = p.G25R on NM_015657.3) | Missense Mutation (SNP) | VAF 80/138 reads (58%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99788110; called by muse, mutect2, varscan2
- ABCB11 | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99791477; called by muse, mutect2, varscan2
- ABCC3 | c.2569G>A p.D857N | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1361744148, COSV53330597; called by muse, mutect2, varscan2
- ABCC6 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as CM073953, COSV52741670, COSV99227993; called by muse, mutect2, varscan2
- ABCG1 | c.1667G>A p.G556E | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1413643910, COSV100493797; called by muse, mutect2, varscan2
- ABHD12B | c.769C>T p.P257S (on ENST00000337334 / NM_001206673.2; = p.P180S on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV99046580; called by muse, mutect2, varscan2
- AC004922.1 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 65/107 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as rs1484907210, COSV99402800; called by muse, mutect2, varscan2
- AC013477.1 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs756489056, COSV99548694; called by muse, mutect2, varscan2
- AC139530.2 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 94/144 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV100230180; called by muse, mutect2, varscan2
- ACAD9 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1391359000, COSV100458919; called by muse, mutect2, varscan2
- ACE | c.3682C>T p.P1228S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs967933744, COSV52005278; called by muse, mutect2, varscan2
- ACO1 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 87/107 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs201567528, COSV100007625; called by muse, mutect2, varscan2
- ACOT1 | c.1110T>G p.C370W | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100233365; called by muse, mutect2, varscan2
- ACOT1 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.85); catalogued as rs1478804372, COSV100233367; called by muse, mutect2, varscan2
- ACSL5 | c.1078G>A p.D360N (on ENST00000354273; = p.D416N on NM_016234.3) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs772970686, COSV100634450, COSV100634463; called by muse, mutect2, varscan2
- ACSM2A | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as rs1451537478, COSV54584896, COSV99524839; called by muse, mutect2, varscan2
- ACSS3 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698231; called by muse, mutect2, varscan2
- ACSS3 | c.1455G>A p.M485I | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs989417666, COSV54087157; called by muse, mutect2, varscan2
- ACSS3 | c.1532G>A p.G511E | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698233; called by muse, mutect2, varscan2
- ACTN2 | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100856508; called by muse, mutect2, varscan2
- ADAM12 | c.2129C>T p.T710I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.073); catalogued as COSV100899955; called by muse, mutect2, varscan2
- ADAM18 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs779557988, COSV55844959; called by muse, mutect2, varscan2
- ADAM18 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as rs747746251, COSV99694766; called by muse, mutect2, varscan2
- ADAM18 | c.1772G>A p.G591E | Missense Mutation (SNP) | VAF 66/89 reads (74%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV99694768; called by muse, mutect2, varscan2
- ADAM2 | c.271T>A p.F91I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.036); catalogued as COSV99696639; called by muse, mutect2
- ADAM23 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100006560; called by muse, mutect2, varscan2
- ADAM23 | c.2278G>A p.D760N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100006563; called by muse, mutect2, varscan2
- ADAM29 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs892611764, COSV100821894; called by muse, mutect2, varscan2
- ADAM29 | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 85/141 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.09); catalogued as rs533209219, COSV63661835, COSV63665401; called by muse, mutect2, varscan2
- ADAM32 | c.1916G>A p.R639K | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1444038889, COSV101165225; called by muse, mutect2, varscan2
- ADAM7 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV99442917; called by muse, mutect2, varscan2
- ADAMTS18 | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 70/103 reads (68%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs1487148464, COSV99271040; called by muse, mutect2, varscan2
- ADAMTS6 | c.2791G>A p.G931R | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs562513614, COSV58685009; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3681G>A p.W1227* | Nonsense Mutation (SNP) | VAF 85/107 reads (79%) | catalogued as COSV99716765; called by muse, mutect2, varscan2
- ADAR | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99425436; called by muse, mutect2, varscan2
- ADCY10 | c.3796G>A p.G1266S | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV100896544; called by muse, varscan2
- ADCY10 | c.2841A>T p.K947N | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as COSV100896545; called by muse, mutect2, varscan2
- ADCY10 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100896546; called by muse, mutect2, varscan2
- ADCY8 | c.3655G>A p.G1219R | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99650581; called by muse, mutect2, varscan2
- ADCY8 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as rs1397738798, COSV99650584; called by muse, mutect2, varscan2
- ADGRA1 | c.61C>T p.H21Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as rs550656034, COSV101658574; called by muse, mutect2, varscan2
- ADGRA2 | c.2611C>T p.P871S | Missense Mutation (SNP) | VAF 67/102 reads (66%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV99604689; called by muse, mutect2, varscan2
- ADGRB3 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs763811697, COSV100999638; called by muse, mutect2, varscan2
- ADGRB3 | c.2915G>A p.G972E | Missense Mutation (SNP) | VAF 71/131 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53235597; called by muse, mutect2, varscan2
- ADGRD1 | c.1075G>A p.G359S | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV55449929; called by muse, mutect2, varscan2
- ADGRF1 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV51944859; called by muse, mutect2, varscan2
- ADGRF4 | c.1843G>A p.G615R | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99347982; called by muse, mutect2, varscan2
- ADGRG3 | c.1365G>A p.W455* | Nonsense Mutation (SNP) | VAF 37/52 reads (71%) | catalogued as COSV100342044; called by muse, mutect2, varscan2
- ADGRV1 | c.16720A>C p.S5574R | Missense Mutation (SNP) | VAF 139/299 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV101315431; called by muse, mutect2, varscan2
- ADRB2 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100019082; called by muse, mutect2, varscan2
- AFM | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867565889, COSV56921393; called by muse, mutect2, varscan2
- AFP | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV56924656; called by muse, mutect2, varscan2
- AGL | c.2809C>G p.Q937E | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99648387; called by muse, mutect2
- AGL | c.4397C>T p.S1466F | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV54059392; called by muse, mutect2, varscan2
- AIM2 | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100931005, COSV104426655; called by muse, mutect2, varscan2
- AIPL1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs267605009, CM156594, COSV100005935; called by muse, mutect2, varscan2
- AK5 | c.1495C>T p.Q499* (on ENST00000354567 / NM_174858.3; = p.Q473* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 15/26 reads (58%) | catalogued as COSV100642357; called by muse, mutect2, varscan2
- AK9 | c.853A>G p.K285E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.027); catalogued as COSV99572309; called by muse, mutect2, varscan2
- AKAP6 | c.6011C>T p.S2004L | Missense Mutation (SNP) | VAF 84/144 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV99798010; called by muse, mutect2, varscan2
- AKNAD1 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100645267; called by muse, mutect2, varscan2
- AKR1A1 | c.432G>A p.W144* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100698670; called by muse, mutect2, varscan2
- AKT2 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 51/76 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV100251360; called by muse, mutect2, varscan2
- AL669918.1 | c.2025-6C>T | Splice Region (SNP) | VAF 23/165 reads (14%) | catalogued as rs778791940, COSV101441035; called by muse, mutect2, varscan2
- ALDH1A3 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 48/61 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100320224; called by muse, mutect2, varscan2
- ALDH5A1 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV100708719; called by muse, mutect2, varscan2
- ALG12 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 25/122 reads (20%) | PolyPhen probably damaging (0.998); catalogued as rs1286752947, COSV100426967; called by muse, mutect2, varscan2
- ALOX12B | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs141890029; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOXE3 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100559597; called by muse, mutect2, varscan2
- AMBRA1 | c.1123C>T p.Q375* (on ENST00000458649 / NM_001367468.1; = p.Q285* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 61/117 reads (52%) | catalogued as COSV54057450; called by muse, mutect2, varscan2
- AMER3 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1200629352, COSV58465055; called by muse, mutect2, varscan2
- AMHR2 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 68/105 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1235526910, COSV57684950; called by muse, mutect2, varscan2
- ANAPC1 | c.5296G>A p.E1766K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs1417055822, COSV100594494; called by mutect2, varscan2
- ANK3 | c.11161C>T p.P3721S | Missense Mutation (SNP) | VAF 75/251 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99778118; called by muse, mutect2, varscan2
- ANK3 | c.9955G>A p.D3319N | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs370076710; called by muse, mutect2, varscan2
- ANK3 | c.7003G>A p.E2335K | Missense Mutation (SNP) | VAF 76/138 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs769392075, COSV55047176; called by muse, mutect2, varscan2
- ANK3 | c.2005C>T p.H669Y | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55071085; called by muse, mutect2, varscan2
- ANKEF1 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65693668; called by muse, mutect2, varscan2
- ANKFN1 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100593067, COSV59457046; called by muse, mutect2, varscan2
- ANKRD17 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1406817744, COSV58215307; called by muse, mutect2, varscan2
- ANKRD44 | c.1862A>C p.N621T | Missense Mutation (SNP) | VAF 107/188 reads (57%) | SIFT tolerated (0.55); PolyPhen benign (0.08); catalogued as COSV99983940; called by muse, mutect2, varscan2
- ANO1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs777037795, COSV100303657, COSV60288254; called by muse, varscan2
- ANO3 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 44/90 reads (49%) | catalogued as COSV99880208; called by muse, mutect2, varscan2
- ANO3 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1488397206, COSV99880209; called by muse, mutect2, varscan2
- ANO4 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.017); catalogued as COSV100151756, COSV54596877; called by muse, mutect2
- ANXA13 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200830719, COSV51625215; called by muse, mutect2, varscan2
- ANXA13 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99146033; called by muse, mutect2, varscan2
- ANXA3 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs144530066; called by muse, mutect2, varscan2
- ANXA5 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 76/127 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99634149; called by muse, mutect2, varscan2
- AP000311.1 | c.437C>G p.A146G | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99285478; called by muse, mutect2, varscan2
- AP1M1 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1410930791, COSV99358114; called by muse, mutect2, varscan2
- AP4B1 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV99870508; called by muse, mutect2
- APOB | c.10690G>A p.E3564K | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99263375; called by muse, mutect2, varscan2
- APOBEC3A | c.96C>A p.Y32* | Nonsense Mutation (SNP) | VAF 60/88 reads (68%) | catalogued as COSV99970282; called by muse, mutect2, varscan2
- APOBEC3B | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as COSV100213641; called by muse, mutect2, varscan2
- ARAP3 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.062); catalogued as COSV99499277; called by muse, mutect2, varscan2
- ARFGEF3 | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.25); catalogued as COSV99292186; called by muse, mutect2, varscan2
- ARFGEF3 | c.1807C>T p.L603F | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1372354774, COSV99292191; called by muse, mutect2, varscan2
- ARHGAP21 | c.3742C>T p.R1248C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1188911173, COSV100255709; called by muse, mutect2, varscan2
- ARHGAP22 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99984371; called by muse, mutect2, varscan2
- ARHGAP26 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1191015382, COSV50835979; called by muse, mutect2, varscan2
- ARHGAP28 | c.2087G>A p.G696E (on ENST00000383472 / NM_001366230.1; = p.G537E on NM_001010000.3) | Missense Mutation (SNP) | VAF 54/64 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58655441; called by muse, mutect2, varscan2
- ARHGAP29 | c.3583G>A p.D1195N | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV99557556; called by muse, mutect2, varscan2
- ARHGAP29 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 68/231 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV99557561; called by muse, mutect2, varscan2
- ARHGAP33 | c.2621C>T p.P874L | Missense Mutation (SNP) | VAF 59/87 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1238304246, COSV99137519; called by muse, mutect2, varscan2
- ARHGAP44 | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV99309996; called by muse, mutect2, varscan2
- ARHGAP5 | c.3572G>A p.R1191K | Missense Mutation (SNP) | VAF 77/129 reads (60%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV61537986; called by muse, mutect2, varscan2
- ARHGEF26 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs1166137862, COSV100726372; called by muse, mutect2, varscan2
- ARID4B | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99934915; called by muse, mutect2, varscan2
- ARMC4 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 69/129 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV100536263; called by muse, mutect2, varscan2
- ARMC4 | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs763662864, COSV100537114, COSV59456453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARMH3 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100898741; called by muse, mutect2, varscan2
- ASH1L | c.4633C>T p.P1545S | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100853088; called by muse, mutect2, varscan2
- ASH1L | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV64214414; called by muse, mutect2, varscan2
- ASTN1 | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99920331; called by muse, mutect2, varscan2
- ASXL3 | c.6709C>T p.P2237S | Missense Mutation (SNP) | VAF 58/69 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs371155785; called by muse, mutect2, varscan2
- ATAD5 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs769837150, COSV100429626; called by muse, mutect2, varscan2
- ATG14 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV99902575; called by muse, mutect2, varscan2
- ATG2B | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 88/171 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100737662; called by muse, mutect2, varscan2
- ATP13A4 | c.3311C>T p.P1104L | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100710052; called by muse, mutect2, varscan2
- ATP2A1 | c.1933A>C p.N645H | Missense Mutation (SNP) | VAF 62/90 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100706797; called by muse, mutect2, varscan2
- ATP2C1 | c.1678A>G p.I560V | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV100146219; called by muse, mutect2, varscan2
- ATP6V0A2 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as rs752531666, COSV100315070; called by muse, varscan2
- ATRNL1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV100744032; called by muse, mutect2, varscan2
- B3GNT3 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 93/123 reads (76%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100427513; called by muse, mutect2, varscan2
- B3GNT7 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs777700169, COSV99805816; called by muse, mutect2, varscan2
- BAZ1A | c.1415A>C p.E472A | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100701082, COSV100701113; called by muse, mutect2, varscan2
- BCL9L | c.4348C>T p.P1450S | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs1359968273, COSV99418485; called by muse, mutect2, varscan2
- BCL9L | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1157752576, COSV52688644; called by muse, mutect2, varscan2
- BEND2 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 93/105 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV66216793, COSV66216973; called by muse, mutect2, varscan2
- BICRAL | c.2770C>T p.R924W | Missense Mutation (SNP) | VAF 65/83 reads (78%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.431); catalogued as rs575050000, COSV58407229; called by muse, mutect2, varscan2
- BIN2 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV57207805, COSV99909122; called by muse, mutect2, varscan2
- BMP7 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV101215399; called by muse, mutect2, varscan2
- BOP1 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100265937, COSV56639676; called by muse, mutect2, varscan2
- BRD4 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV99649884; called by muse, mutect2, varscan2
- BRINP2 | c.380G>A p.R127K | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100837813; called by muse, mutect2, varscan2
- BRS3 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 79/84 reads (94%) | catalogued as COSV101036419; called by muse, mutect2, varscan2
- BRWD1 | c.2416G>A p.G806S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs1368026723, COSV100312708; called by muse, mutect2, varscan2
- BTBD8 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1331277634, COSV100730094; called by muse, mutect2, varscan2
- BTN1A1 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as rs1310079675, COSV55067376; called by muse, mutect2, varscan2
- C10orf120 | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV61492312, COSV61492453; called by muse, mutect2, varscan2
- C2CD6 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as rs747456159, COSV53792143; called by muse, mutect2, varscan2
- C2orf16 | c.5515C>T p.R1839C | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1233876003, COSV100820631; called by muse, mutect2, varscan2
- C4orf33 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV99828827; called by muse, mutect2, varscan2
- C6 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867222895, COSV54718556; called by muse, mutect2, varscan2
- C7 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs758903222, COSV100495342; called by muse, mutect2, varscan2
- C8A | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 62/107 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV63483594; called by muse, mutect2, varscan2
- CA8 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100526634; called by muse, mutect2, varscan2
- CAB39 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV51480035; called by muse, mutect2, varscan2
- CABS1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 78/120 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV99908922; called by muse, mutect2, varscan2
- CABS1 | c.285A>T p.E95D | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV99908924; called by muse, mutect2, varscan2
- CACNA1D | c.4486G>A p.A1496T (on ENST00000350061 / NM_001128840.3; = p.A1516T on NM_000720.4) | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55455525, COSV99856475; called by muse, mutect2, varscan2
- CACNA1I | c.1817G>A p.G606E | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1297476028, COSV100359086; called by muse, varscan2
- CACNA2D1 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100665682; called by muse, mutect2, varscan2
- CACNA2D1 | c.297C>T p.R99= | Splice Region (SNP) | VAF 40/187 reads (21%) | catalogued as rs776437957, COSV100665684; called by muse, mutect2, varscan2
- CACNG4 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV100047318; called by muse, mutect2, varscan2
- CAMK1D | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.614); catalogued as rs768414434, COSV101123402; called by muse, mutect2, varscan2
- CAMSAP2 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1266543412, COSV99372804; called by muse, mutect2, varscan2
- CAND2 | c.1226C>T p.P409L (on ENST00000456430 / NM_001162499.2; = p.P316L on NM_012298.3) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs774361974, COSV99928550; called by muse, mutect2, varscan2
- CAPN11 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as rs765871453, COSV67238281; called by muse, mutect2, varscan2
- CAPN13 | c.1693C>T p.R565* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as rs374855001; called by muse, mutect2, varscan2
- CAPN6 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 220/241 reads (91%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV100136665; called by muse, mutect2, varscan2
- CAPSL | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV68437872; called by muse, mutect2, varscan2
- CAPZA2 | c.367T>C p.S123P | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV100753814; called by muse, mutect2, varscan2
- CARD11 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100712197, COSV62716688; called by muse, mutect2, varscan2
- CARD6 | c.2774C>T p.S925L | Missense Mutation (SNP) | VAF 78/131 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV99620117; called by muse, mutect2, varscan2
- CARMIL1 | c.1143G>A p.M381I | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.07); catalogued as COSV100276751; called by muse, mutect2
- CARMIL2 | c.3377G>A p.R1126Q | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs756446842, COSV54667968; called by muse, mutect2, varscan2
- CARS1 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs529526134, COSV99541896; called by muse, mutect2, varscan2
- CASP1 | c.1121G>A p.R374Q (on ENST00000436863 / NM_033292.4; = p.R353Q on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1024902270, COSV52830913, COSV99507165; called by muse, mutect2, varscan2
- CASP14 | c.177+1G>A p.X59_splice | Splice Site (SNP) | VAF 98/135 reads (73%) | catalogued as COSV55664861; called by muse, mutect2, varscan2
- CASP8AP2 | c.5840C>T p.S1947L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99386728; called by muse, mutect2, varscan2
- CASQ1 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV100850115; called by muse, mutect2
- CASZ1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV100680682; called by muse, mutect2, varscan2
- CATSPER4 | c.1200G>A p.M400I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100128187; called by muse, mutect2, varscan2
- CCDC105 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as COSV52963797; called by muse, mutect2, varscan2
- CCDC130 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99681115; called by muse, mutect2, varscan2
- CCDC146 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV53546929; called by muse, mutect2, varscan2
- CCDC158 | c.3188G>A p.G1063E | Missense Mutation (SNP) | VAF 87/170 reads (51%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); catalogued as COSV101187140; called by muse, mutect2, varscan2
- CCDC178 | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 70/80 reads (88%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV55783290; called by muse, mutect2, varscan2
- CCDC180 | c.4943C>T p.S1648F | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100826539; called by muse, mutect2, varscan2
- CCDC27 | c.1550G>A p.R517K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.85); PolyPhen benign (0.054); catalogued as COSV99622025; called by muse, mutect2, varscan2
- CCDC30 | c.1942G>A p.E648K (on ENST00000340612; = p.E605K on NM_001080850.3) | Missense Mutation (SNP) | VAF 45/71 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as COSV59607662; called by muse, mutect2, varscan2
- CCDC39 | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV99867037; called by muse, mutect2, varscan2
- CCDC62 | c.1814T>A p.L605* | Nonsense Mutation (SNP) | VAF 38/184 reads (21%) | catalogued as COSV99456547; called by muse, mutect2, varscan2
- CCDC68 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 57/66 reads (86%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100491588; called by muse, mutect2, varscan2
- CCER1 | c.300G>A p.W100* | Nonsense Mutation (SNP) | VAF 28/45 reads (62%) | catalogued as COSV62645907; called by muse, mutect2, varscan2
- CCL11 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100005473; called by muse, mutect2, varscan2
- CCN4 | c.874A>C p.S292R | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99136942; called by muse, mutect2, varscan2
- CCNB3 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 86/91 reads (95%) | catalogued as COSV99328391; called by muse, mutect2, varscan2
- CCT7 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as COSV99240501; called by muse, mutect2, varscan2
- CCT8L2 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 156/207 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63464286; called by muse, mutect2, varscan2
- CD163L1 | c.3892G>A p.D1298N | Missense Mutation (SNP) | VAF 80/117 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV58023463; called by muse, mutect2, varscan2
- CD1A | c.198C>A p.F66L | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV99192153, COSV99192154; called by muse, mutect2, varscan2
- CD1B | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 19/165 reads (12%) | catalogued as COSV100939122; called by muse, mutect2, varscan2
- CD2 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV65644445; called by muse, mutect2, varscan2
- CD209 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 292/417 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs759390544, COSV99213606; called by muse, mutect2, varscan2
- CD48 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 92/247 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs1558029886, COSV100924183, COSV63567610; called by muse, mutect2, varscan2
- CD86 | c.894-1G>A p.X298_splice (on ENST00000330540 / NM_175862.5; = p.X292_splice on NM_006889.4) | Splice Site (SNP) | VAF 30/97 reads (31%) | catalogued as rs1224750195, COSV100053817; called by muse, mutect2, varscan2
- CDC37L1 | c.161G>T p.C54F | Missense Mutation (SNP) | VAF 48/55 reads (87%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV101116463; called by muse, mutect2, varscan2
- CDH10 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 88/140 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866233508, COSV100049918, COSV52582412; called by muse, mutect2, varscan2
- CDH22 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 90/154 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745978636, COSV100952693; called by muse, mutect2, varscan2
- CDH23 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs909705325, COSV54955943; called by muse, mutect2, varscan2
- CDH23 | c.2242G>C p.A748P | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54952692, COSV99818631, COSV99823209; called by muse, mutect2, varscan2
- CDH23 | c.7081G>A p.D2361N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765403330, COSV99818635; called by muse, mutect2, varscan2
- CDH9 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 29/115 reads (25%) | catalogued as rs779923057, COSV50275360, COSV50343795; called by muse, mutect2, varscan2
- CDH9 | c.89G>A p.S30N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV50381618, COSV99141413; called by muse, mutect2, varscan2
- CEBPE | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV99247321; called by muse, mutect2, varscan2
- CEP170 | c.3268A>G p.T1090A | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.388); catalogued as COSV100316333; called by muse, mutect2, varscan2
- CEP170B | c.2357C>G p.S786* (on ENST00000453495; = p.S715* on NM_015005.3) | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as COSV101371379; called by muse, mutect2, varscan2
- CEP19 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 66/116 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99582131; called by muse, mutect2, varscan2
- CEP70 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs1455268825, COSV53876770; called by muse, mutect2, varscan2
- CETN1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 55/66 reads (83%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as rs1400464859, COSV100511196; called by muse, mutect2, varscan2
- CFAP300 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 90/116 reads (78%) | catalogued as COSV101462443; called by muse, mutect2, varscan2
- CFAP43 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99530338; called by muse, mutect2
- CFAP43 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as rs1194012606, COSV99530339; called by muse, mutect2, varscan2
- CFAP44 | c.1779+2T>A p.X593_splice | Splice Site (SNP) | VAF 20/90 reads (22%) | catalogued as COSV99868819; called by muse, mutect2
- CFAP45 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs1299748087, COSV63648762; called by muse, mutect2, varscan2
- CFAP47 | c.2774C>T p.S925F | Missense Mutation (SNP) | VAF 51/53 reads (96%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs1356351185, COSV52892792; called by muse, mutect2, varscan2
- CFAP54 | c.5321C>T p.S1774L | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV61572150; called by muse, mutect2, varscan2
- CFAP58 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.206); catalogued as rs762542201, COSV100459119, COSV57211406; called by muse, mutect2, varscan2
- CFAP58 | c.2585G>A p.G862E | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63832696, COSV63834484; called by muse, mutect2, varscan2
- CFAP97 | c.1532T>C p.V511A | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV101515136; called by muse, mutect2, varscan2
- CFHR5 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56831078; called by muse, mutect2, varscan2
- CFHR5 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.154); catalogued as COSV99887858; called by muse, mutect2, varscan2
- CFTR | c.3994C>T p.P1332S | Missense Mutation (SNP) | VAF 102/271 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV50071178; called by muse, mutect2, varscan2
- CHD8 | c.5881C>T p.R1961C (on ENST00000646647 / NM_001170629.2; = p.R1682C on NM_020920.4) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV100765239; called by muse, mutect2, varscan2
- CHGB | c.1763A>C p.N588T | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100972901; called by muse, mutect2, varscan2
- CIC | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV99358887; called by muse, mutect2, varscan2
- CILP | c.3103C>T p.R1035* | Nonsense Mutation (SNP) | VAF 44/51 reads (86%) | catalogued as rs771794833, COSV56026156; called by muse, mutect2, varscan2
- CIT | c.3731G>A p.R1244Q | Missense Mutation (SNP) | VAF 57/88 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs750567021, COSV55873718; called by muse, mutect2, varscan2
- CIT | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs752750796, COSV55869624; called by muse, mutect2, varscan2
- CLCN1 | c.2534G>A p.G845D | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100577671; called by muse, mutect2, varscan2
- CLCN6 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100411543; called by muse, mutect2, varscan2
- CLCNKB | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100989628; called by muse, mutect2, varscan2
- CLEC17A | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); catalogued as rs200257988, COSV60426797; called by muse, mutect2, varscan2
- CLGN | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as COSV57776489; called by muse, mutect2, varscan2
- CMKLR1 | c.521C>T p.S174F (on ENST00000312143 / NM_001142344.2; = p.S172F on NM_004072.3) | Missense Mutation (SNP) | VAF 46/65 reads (71%) | SIFT tolerated (0.56); PolyPhen benign (0.111); catalogued as COSV100379175, COSV56441348; called by muse, mutect2, varscan2
- CNGA2 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 50/55 reads (91%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV61703584, COSV61706403; called by muse, mutect2, varscan2
- CNGA3 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1374130283, COSV99735981, COSV99736913; called by muse, mutect2, varscan2
- CNTNAP2 | c.2826G>A p.M942I | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs796052380, COSV62218712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COG7 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV100207355; called by muse, mutect2, varscan2
- COL11A2 | c.3941del p.P1314Qfs*31 (on ENST00000341947 / NM_080680.3; = p.P1207Qfs*31 on NM_080679.2) | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs1223246567; called by pindel, varscan2
- COL16A1 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.521); catalogued as COSV99593465; called by muse, mutect2, varscan2
- COL16A1 | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1472628116, COSV99593476; called by muse, mutect2, varscan2
- COL17A1 | c.2949G>A p.G983= | Splice Region (SNP) | VAF 35/85 reads (41%) | catalogued as COSV100793385, COSV62228022; called by muse, mutect2, varscan2
- COL1A2 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as rs1434292644, COSV99798437; called by muse, mutect2, varscan2
- COL22A1 | c.4615+1G>A p.X1539_splice | Splice Site (SNP) | VAF 46/90 reads (51%) | catalogued as rs1333809746, COSV100276129, COSV100278383; called by muse, varscan2
- COL26A1 | c.739G>A p.G247R (on ENST00000313669 / NM_001278563.3; = p.G245R on NM_133457.4) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363632412, COSV100561440; called by muse, mutect2, varscan2
- COL26A1 | c.740G>T p.G247V (on ENST00000313669 / NM_001278563.3; = p.G245V on NM_133457.4) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1452035493, COSV100561442; called by muse, mutect2, varscan2
- COL28A1 | c.3204G>A p.E1068= | Splice Region (SNP) | VAF 52/111 reads (47%) | catalogued as rs1402797790, COSV101258289; called by muse, mutect2, varscan2
- COL3A1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58589665; called by muse, mutect2, varscan2
- COL4A5 | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.867); catalogued as rs771538814, COSV60356642; called by muse, varscan2
- COL4A5 | c.4357C>T p.P1453S | Missense Mutation (SNP) | VAF 93/107 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100086374, COSV60364825; called by muse, mutect2, varscan2
- COL6A6 | c.2840G>A p.G947E | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100649746, COSV62027245; called by muse, mutect2, varscan2
- COL6A6 | c.6031G>A p.A2011T | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100649750; called by muse, mutect2, varscan2
- COL7A1 | c.5767G>A p.E1923K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs781342109, COSV100094913; called by muse, mutect2, varscan2
- COX10 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1384737990, COSV99885944; called by muse, mutect2, varscan2
- CPAMD8 | c.572G>A p.R191Q (on ENST00000651564; = p.R144Q on NM_015692.5) | Missense Mutation (SNP) | VAF 153/219 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs756382422, COSV52234053; called by muse, mutect2, varscan2
- CPSF1 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV100450152; called by muse, mutect2, varscan2
- CPT1C | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 25/141 reads (18%) | catalogued as rs749529596, COSV99773213; called by muse, mutect2, varscan2
- CPXM2 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV99580929; called by muse, mutect2, varscan2
- CRACDL | c.2591C>T p.P864L | Missense Mutation (SNP) | VAF 70/113 reads (62%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.646); catalogued as rs1322863388, COSV101193975; called by muse, mutect2, varscan2
- CRISP3 | c.516G>A p.Q172= (on ENST00000371159 / NM_001368123.1; = p.Q154= on NM_006061.4) | Splice Region (SNP) | VAF 47/214 reads (22%) | catalogued as COSV99538560; called by muse, mutect2, varscan2
- CRMP1 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs755012630, COSV61478290, COSV61479919; called by muse, mutect2, varscan2
- CRY1 | c.1287C>T p.I429= | Splice Region (SNP) | VAF 73/98 reads (74%) | catalogued as COSV99150339; called by muse, mutect2, varscan2
- CRYBG1 | c.3923C>T p.S1308F | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV100954368; called by muse, mutect2, varscan2
- CSF1R | c.2901C>A p.N967K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs1229684506, COSV99640733; called by muse, mutect2, varscan2
- CSF2RB | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1403979041, COSV99453218; called by muse, mutect2
- CSMD1 | c.9235C>T p.R3079C (on ENST00000520002; = p.R3078C on NM_033225.6) | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.536); catalogued as rs766431836, COSV59298141; called by muse, mutect2, varscan2
- CSMD1 | c.8967G>A p.M2989I (on ENST00000520002; = p.M2988I on NM_033225.6) | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as rs749027559, COSV59322288; called by muse, mutect2, varscan2
- CSMD1 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 116/214 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101213059; called by muse, varscan2
- CSMD2 | c.4093G>A p.D1365N | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99585503; called by muse, mutect2, varscan2
- CSMD2 | c.3722G>A p.G1241E | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99585509; called by muse, mutect2, varscan2
- CSNK1D | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV99484352, COSV99484557; called by muse, mutect2, varscan2
- CSPP1 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs745897839, COSV99137986; called by muse, mutect2, varscan2
- CST4 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.052); catalogued as rs146152326, COSV54149907; called by muse, mutect2, varscan2
- CT55 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99358781; called by muse, mutect2, varscan2
- CTAGE15 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV101372105; called by muse, mutect2, varscan2
- CTBP1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs1490704176, COSV99337420; called by muse, mutect2, varscan2
- CTSC | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 46/110 reads (42%) | catalogued as rs1409888746, CM002938, COSV57056428; called by muse, mutect2, varscan2
- CTSE | c.529C>T p.P177S (on ENST00000360218; = p.P172S on NM_001910.4) | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100733472; called by muse, mutect2, varscan2
- CTSE | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as rs1553278852, COSV100733448; called by muse, mutect2, varscan2
- CTTNBP2 | c.1661A>T p.Q554L | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99352921; called by muse, mutect2, varscan2
- CUX2 | c.1125G>A p.M375I | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV55650629; called by muse, mutect2, varscan2
- CUX2 | c.2426C>T p.S809F | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99918512; called by muse, mutect2, varscan2
- CYFIP2 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.863); catalogued as rs1459314371, COSV100555564; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP11B1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99454478; called by muse, mutect2, varscan2
- CYP24A1 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 110/190 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99398019; called by muse, mutect2, varscan2
- CYP4A22 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 65/109 reads (60%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs765755173, COSV53740527; called by muse, mutect2, varscan2
- CYP4F11 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV56130036; called by muse, mutect2, varscan2
- DAAM1 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs150648068; called by muse, mutect2, varscan2
- DAB1 | c.1603G>A p.D535N (on ENST00000371231; = p.D502N on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs868393955, COSV100976130; called by muse, mutect2, varscan2
- DAB1 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV100139361; called by muse, mutect2, varscan2
- DAB2IP | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 38/139 reads (27%) | catalogued as COSV99404632; called by muse, mutect2, varscan2
- DACH1 | c.1654C>T p.P552S (on ENST00000619232 / NM_001366712.1; = p.P500S on NM_080759.6) | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.351); catalogued as COSV57490796; called by muse, mutect2, varscan2
- DAXX | c.2216C>T p.S739F | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99801379; called by muse, mutect2, varscan2
- DBX1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99910095; called by muse, mutect2, varscan2
- DCAF1 | c.2734C>T p.R912C | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs782593092, COSV60047817; called by muse, mutect2, varscan2
- DCAF4L2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV60482201; called by muse, mutect2, varscan2
- DCDC1 | c.3295G>A p.D1099N (on ENST00000597505 / NM_001367979.1; = p.D206N on NM_020869.3) | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.203); catalogued as COSV100337807; called by muse, mutect2, varscan2
- DDAH1 | c.686A>G p.N229S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99394564; called by muse, mutect2, varscan2
- DDX3X | c.1426C>T p.Q476* (on ENST00000399959; = p.Q477* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 60/67 reads (90%) | catalogued as COSV67864549; called by muse, mutect2, varscan2
- DDX60 | c.4200C>G p.F1400L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs371200444, COSV101190225; called by muse, mutect2, varscan2
- DENND10 | c.482-2A>C p.X161_splice | Splice Site (SNP) | VAF 24/48 reads (50%) | catalogued as COSV100813963; called by muse, mutect2, varscan2
- DENND1C | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs374964139; called by muse, varscan2
- DENND3 | c.1600C>T p.H534Y | Missense Mutation (SNP) | VAF 117/226 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52802565; called by muse, mutect2, varscan2
- DGKH | c.3239G>A p.R1080Q | Missense Mutation (SNP) | VAF 140/222 reads (63%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs757237325, COSV99818256; called by muse, mutect2, varscan2
- DHX15 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.73); catalogued as rs751138616, COSV100391112; called by muse, mutect2, varscan2
- DHX29 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99286921; called by muse, mutect2, varscan2
- DHX29 | c.1183C>G p.P395A | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV99286923; called by muse, mutect2, varscan2
- DHX35 | c.175-1G>A p.X59_splice | Splice Site (SNP) | VAF 16/54 reads (30%) | catalogued as rs79685926, COSV99326370; called by muse, mutect2
- DHX36 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV100273269; called by muse, mutect2, varscan2
- DHX8 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV99291862; called by muse, mutect2, varscan2
- DIDO1 | c.845T>G p.M282R | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99824574; called by muse, mutect2, varscan2
- DIS3L2 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs745989142, COSV56054679; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISP1 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52655014; called by muse, mutect2, varscan2
- DISP1 | c.3077C>T p.S1026F | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as COSV52654419; called by muse, mutect2, varscan2
- DLL3 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 68/95 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV99218681; called by muse, mutect2, varscan2
- DLX6 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.561); catalogued as rs1176841218, COSV99142192; called by muse, mutect2
- DMBT1 | c.841A>C p.M281L | Missense Mutation (SNP) | VAF 119/274 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV100351952; called by muse, mutect2, varscan2
- DMBT1 | c.3643G>A p.E1215K (on ENST00000338354 / NM_001377530.1; = p.E716K on NM_004406.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV100351956; called by mutect2, varscan2
- DMGDH | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 66/256 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99668414; called by muse, mutect2, varscan2
- DNAAF1 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.04); catalogued as COSV57579196; called by muse, mutect2, varscan2
- DNAAF3 | c.991G>A p.G331R (on ENST00000524407 / NM_001256715.2; = p.G378R on NM_178837.4) | Missense Mutation (SNP) | VAF 96/135 reads (71%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs7508641, COSV100787833, COSV61276050; called by muse, mutect2, varscan2
- DNAAF3 | c.740C>A p.A247D (on ENST00000524407 / NM_001256715.2; = p.A294D on NM_178837.4) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100787834; called by muse, mutect2, varscan2
- DNAH10 | c.3747G>A p.M1249I (on ENST00000409039; = p.M1188I on NM_207437.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101291915; called by muse, mutect2, varscan2
- DNAH11 | c.11083G>A p.E3695K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV100176769; called by muse, mutect2, varscan2
- DNAH2 | c.7735G>A p.E2579K | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV101208972; called by muse, mutect2, varscan2
- DNAH3 | c.10159G>A p.E3387K | Missense Mutation (SNP) | VAF 55/78 reads (71%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54504699, COSV54505840; called by muse, mutect2, varscan2
- DNAH3 | c.6800C>T p.S2267L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs143853702; called by muse, mutect2, varscan2
- DNAH3 | c.4280C>T p.P1427L | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99764750; called by muse, mutect2, varscan2
- DNAH5 | c.11443G>A p.E3815K | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54232622; called by muse, mutect2, varscan2
- DNAH5 | c.10667C>T p.P3556L | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1179894393, COSV54205876; called by muse, mutect2, varscan2
- DNAH5 | c.7909G>A p.D2637N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54226436; called by muse, mutect2, varscan2
- DNAH5 | c.4450G>T p.E1484* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV99444529; called by muse, mutect2, varscan2
- DNAH5 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as rs1395647219, COSV99444533; called by muse, mutect2, varscan2
- DNAH7 | c.8281C>T p.P2761S | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV56783424; called by muse, mutect2, varscan2
- DNAH9 | c.863A>T p.Y288F | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99303805; called by muse, mutect2, varscan2
- DNAH9 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.091); catalogued as rs750495023, COSV99303808; called by muse, mutect2, varscan2
- DNAI2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.169); catalogued as COSV56762993; called by muse, mutect2, varscan2
- DNAJB4 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 33/95 reads (35%) | catalogued as rs141666453, COSV66131887; called by muse, mutect2, varscan2
- DNMBP | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV100143028; called by muse, mutect2, varscan2
- DOCK11 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99352776; called by muse, mutect2, varscan2
- DOCK11 | c.5702G>A p.R1901K | Missense Mutation (SNP) | VAF 85/95 reads (89%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99352779; called by muse, mutect2, varscan2
- DOCK3 | c.3595C>A p.R1199S | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99808909; called by muse, mutect2, varscan2
- DOCK5 | c.2801G>A p.R934K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99375937; called by muse, mutect2, varscan2
- DOCK7 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51999519; called by muse, mutect2, varscan2
- DOK3 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1329137681, COSV100466794; called by muse, mutect2, varscan2
- DOK6 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 74/82 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV101234220; called by muse, mutect2, varscan2
- DOT1L | c.3959G>C p.G1320A | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.165); catalogued as COSV101288496; called by muse, mutect2, varscan2
- DPP10 | c.1444T>A p.F482I | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV100058053; called by muse, mutect2, varscan2
- DPP6 | c.2023G>A p.E675K (on ENST00000377770 / NM_001364500.2; = p.E613K on NM_001936.5) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs377194563; called by muse, mutect2, varscan2
- DPYD | c.2393C>T p.S798F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100928504; called by muse, mutect2, varscan2
- DPYS | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1488848521, COSV100679281, COSV60913715; called by muse, mutect2, varscan2
- DPYSL2 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 82/131 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1335681733, COSV100233560; called by muse, mutect2, varscan2
- DPYSL3 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as COSV100574874; called by muse, mutect2, varscan2
- DSE | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs267600774, COSV59062498; called by muse, mutect2, varscan2
- DSP | c.6709G>A p.E2237K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.265); catalogued as COSV101131174; called by muse, mutect2, varscan2
- DUXA | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV101617120, COSV73729491; called by muse, mutect2, varscan2
- DYSF | c.4405A>G p.I1469V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1178233698, COSV99244040; called by muse, mutect2, varscan2
- DYSF | c.4417G>A p.E1473K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50323682, COSV99244041; called by muse, mutect2, varscan2
- EAPP | c.119A>G p.Q40R | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV51653464, COSV99164210; called by muse, mutect2, varscan2
- EBF2 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1306542768, COSV101282088; called by muse, mutect2, varscan2
- EEF2 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100500551; called by muse, mutect2, varscan2
- EFCAB2 | c.628G>A p.E210K (on ENST00000366522; = p.E74K on NM_032328.3) | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.852); catalogued as rs557402578, COSV63655620; called by muse, mutect2
- EFCAB6 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 94/142 reads (66%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as COSV99412354; called by muse, mutect2
- EFCAB6 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.408); catalogued as rs200749675, COSV99412091; called by muse, mutect2, varscan2
- EHBP1 | c.2127G>A p.M709I | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV99859939; called by muse, mutect2, varscan2
- EHMT2 | c.2684C>T p.S895F | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64997856; called by muse, mutect2, varscan2
- EHMT2 | c.545G>T p.R182L | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs1473305590, COSV100976946, COSV64993752; called by muse, mutect2, varscan2
- EIF3A | c.2123C>T p.P708L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100974478; called by muse, mutect2, varscan2
- ELANE | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as CD132354, COSV99708650; called by muse, mutect2, varscan2
- ELAPOR1 | c.2914G>A p.D972N | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747211369, COSV64040535; called by muse, mutect2, varscan2
- ELAVL2 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 104/121 reads (86%) | catalogued as rs867496241, COSV99805296; called by muse, mutect2, varscan2
- ELAVL4 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV100836530; called by muse, mutect2, varscan2
- ELN | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV52713258, COSV99332185; called by muse, mutect2, varscan2
- ELP5 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100020995, COSV59708338; called by muse, mutect2, varscan2
- EMILIN1 | c.2653G>A p.G885S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV99565703; called by muse, mutect2, varscan2
- EML1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs201185419, COSV51743152; called by muse, mutect2, varscan2
- EMSY | c.2615A>G p.H872R | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.3); catalogued as COSV100595341; called by muse, mutect2, varscan2
- ENPEP | c.1652G>A p.G551D | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1368326252, COSV99486956; called by muse, mutect2, varscan2
- EPB41 | c.2070G>T p.K690N (on ENST00000343067 / NM_001166005.2; = p.K448N on NM_004437.4) | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV58040645; called by muse, mutect2, varscan2
- EPB41L1 | c.2023A>G p.I675V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99148840; called by muse, mutect2, varscan2
- EPHA6 | c.2501G>A p.R834K (on ENST00000389672 / NM_001080448.3; = p.R226K on NM_173655.4) | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.048); catalogued as COSV101060754; called by muse, mutect2, varscan2
- EPHA7 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 64/125 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs754119070, COSV65179395; called by muse, mutect2, varscan2
- EPHA7 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 86/140 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1165179670, COSV65177943; called by muse, mutect2, varscan2
- EPHA7 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.377); catalogued as COSV65170292; called by muse, mutect2, varscan2
- EPHB1 | c.1769G>A p.G590E | Missense Mutation (SNP) | VAF 99/163 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV67662871, COSV67669274; called by muse, mutect2, varscan2
- EPHB6 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs753791648, COSV100844105; called by muse, mutect2, varscan2
- EPRS1 | c.3922C>T p.P1308S | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859298; called by muse, mutect2, varscan2
- EPS15 | c.2278del p.T760Hfs*43 | Frame Shift Del (DEL) | VAF 39/89 reads (44%) | catalogued as COSV65540765; called by mutect2, pindel, varscan2
- EPS15L1 | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs757841102, COSV99932651; called by muse, mutect2, varscan2
- ERBB2 | c.3290G>A p.G1097E | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99506535; called by muse, mutect2, varscan2
- ERBB4 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs267599191, COSV53505317; called by muse, mutect2, varscan2
- ERC2 | c.1616G>A p.R539K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); catalogued as COSV55609891; called by muse, mutect2, varscan2
- ERC2 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs868457485, COSV55675891; called by muse, mutect2, varscan2
- ERC2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 163/294 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55597408; called by muse, mutect2, varscan2
- ERCC6 | c.3268C>T p.P1090S | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.026); catalogued as COSV100875644; called by muse, mutect2, varscan2
- ERI1 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV51571763; called by muse, mutect2, varscan2
- ERICH3 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.148); catalogued as COSV100443282; called by muse, mutect2, varscan2
- ERICH3 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58611116; called by muse, mutect2, varscan2
- EVI2B | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs747146449, COSV100445369; called by muse, mutect2, varscan2
- EYA1 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100378451; called by muse, mutect2, varscan2
- EYA4 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as rs1394230343, COSV100765138; called by muse, mutect2, varscan2
- F11 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs768474112, CS081910, COSV99251144, COSV99251295; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- F11 | c.325+1G>A p.X109_splice | Splice Site (SNP) | VAF 17/54 reads (31%) | catalogued as rs140190776, CS063303; called by muse, mutect2, varscan2
- F13A1 | c.1051A>T p.M351L | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV99342097; called by muse, mutect2, varscan2
- F2 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV61314929, COSV61317280; called by muse, mutect2, varscan2
- F5 | c.1299C>T p.I433= | Splice Region (SNP) | VAF 28/108 reads (26%) | catalogued as rs541673477, COSV63121250; called by muse, mutect2, varscan2
- FAAP100 | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | catalogued as COSV59885782; called by muse, mutect2, varscan2
- FAM131C | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV65153079; called by muse, mutect2, varscan2
- FAM135A | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.994); catalogued as rs764762660, COSV99525149; called by muse, mutect2, varscan2
- FAM135B | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as rs370285922; called by muse, mutect2, varscan2
- FAM160B2 | c.1960G>A p.G654S | Missense Mutation (SNP) | VAF 69/121 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as rs752175859, COSV99248697; called by muse, mutect2, varscan2
- FAM160B2 | c.1961G>A p.G654D | Missense Mutation (SNP) | VAF 70/121 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99248699; called by muse, mutect2, varscan2
- FAM171A1 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 77/121 reads (64%) | catalogued as COSV65313231; called by muse, mutect2, varscan2
- FAM184A | c.2274G>A p.M758I | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV100137326; called by muse, mutect2, varscan2
- FAM217B | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV100674367; called by muse, mutect2, varscan2
- FAM237A | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.641); catalogued as COSV101405564, COSV101405580; called by muse, mutect2, varscan2
- FAM53C | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53512583; called by muse, mutect2, varscan2
- FAM83B | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs868155358, COSV60924635; called by muse, mutect2, varscan2
- FAM83B | c.2507C>T p.S836L | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV100173983; called by muse, mutect2, varscan2
- FAM83H | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1554623503, COSV101186915; called by muse, mutect2, varscan2
- FANCD2 | c.3469T>G p.S1157A | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.384); catalogued as COSV99810257; called by muse, mutect2, varscan2
- FANCM | c.3652G>A p.E1218K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV99950376; called by muse, mutect2, varscan2
- FARSB | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV99918103; called by muse, mutect2, varscan2
- FAT3 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV53196187; called by muse, mutect2, varscan2
- FAT3 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 58/69 reads (84%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV53158657, COSV99961459; called by muse, mutect2, varscan2
- FAT3 | c.12682C>T p.P4228S | Missense Mutation (SNP) | VAF 70/89 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1239521629, COSV99961462; called by muse, mutect2, varscan2
- FAT4 | c.12411G>A p.M4137I | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.758); catalogued as COSV100627166; called by muse, mutect2, varscan2
- FBN3 | c.6616C>T p.R2206* | Nonsense Mutation (SNP) | VAF 31/143 reads (22%) | catalogued as rs150404330; called by muse, mutect2, varscan2
- FBN3 | c.6160G>A p.E2054K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs149936210; called by muse, mutect2, varscan2
- FBXL20 | c.265T>C p.C89R | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1353925955, COSV99233692; called by muse, mutect2, varscan2
- FBXO2 | c.523T>A p.W175R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.362); catalogued as COSV99278721; called by muse, mutect2, varscan2
- FBXW5 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774723521, COSV99812312; called by muse, mutect2, varscan2
- FER1L6 | c.3040C>T p.R1014W | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867750959, COSV67551382; called by muse, mutect2, varscan2
- FER1L6 | c.3934C>T p.L1312F | Missense Mutation (SNP) | VAF 112/274 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.11); catalogued as COSV101205399, COSV67552974; called by muse, mutect2, varscan2
- FGA | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV57397265; called by muse, mutect2, varscan2
- FGFBP1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as rs754608281, COSV99468902; called by muse, mutect2, varscan2
- FGFR1 | c.1352C>T p.S451F (on ENST00000447712 / NM_023110.3; = p.S449F on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/137 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100247380; called by muse, mutect2, varscan2
- FGFR1OP2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1169395956, COSV99986788; called by muse, mutect2, varscan2
- FKTN | c.60T>G p.F20L | Missense Mutation (SNP) | VAF 78/93 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99795250; called by muse, mutect2, varscan2
- FLG | c.10933G>C p.G3645R | Missense Mutation (SNP) | VAF 119/1023 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.741); catalogued as rs750903733, COSV100910450, COSV64241634; called by muse, mutect2, varscan2
- FLG | c.8359C>T p.R2787C | Missense Mutation (SNP) | VAF 96/1656 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.248); catalogued as rs750753155, COSV64235824; called by muse, mutect2
- FLG | c.6415C>T p.R2139C | Missense Mutation (SNP) | VAF 212/900 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as rs758203305, COSV64243402, COSV64244746; called by muse, mutect2, varscan2
- FLG | c.4391G>A p.G1464E | Missense Mutation (SNP) | VAF 71/416 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.746); catalogued as COSV64243483; called by muse, mutect2, varscan2
- FLG | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 154/482 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as rs539986712, COSV100910455; called by muse, varscan2
- FLG | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 236/646 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs912328039, COSV64240961; called by muse, varscan2
- FLG2 | c.1721C>T p.S574L | Missense Mutation (SNP) | VAF 104/685 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV101165581; called by muse, mutect2, varscan2
- FLNC | c.1864G>A p.G622R | Missense Mutation (SNP) | VAF 71/233 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100367585; called by muse, mutect2, varscan2
- FLNC | c.2813G>A p.G938D | Missense Mutation (SNP) | VAF 214/334 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100367586; called by muse, mutect2, varscan2
- FLT1 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.314); catalogued as COSV56742622, COSV56743924; called by muse, mutect2, varscan2
- FLVCR1 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874991; called by muse, mutect2, varscan2
- FMN2 | c.3650T>C p.I1217T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.067); catalogued as COSV100142036, COSV100142384; called by muse, mutect2
- FMN2 | c.4349G>A p.R1450Q | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765785282, COSV60428519; called by muse, mutect2, varscan2
- FOS | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs775485425, COSV100338406; called by muse, mutect2, varscan2
- FOXA1 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as rs761789499, COSV99163189; called by muse, mutect2, varscan2
- FOXK2 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV58879258; called by muse, mutect2, varscan2
- FOXO1 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs374649965, COSV101091740; called by muse, mutect2, varscan2
- FOXP1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV100560792; called by muse, mutect2, varscan2
- FOXS1 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV99639442; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV63042821; called by muse, mutect2, varscan2
- FRAS1 | c.11962T>C p.F3988L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0.037); catalogued as COSV99347917; called by muse, mutect2, varscan2
- FREM2 | c.9352A>G p.T3118A | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV99746635; called by muse, mutect2, varscan2
- FRMD1 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs1289449303, COSV99349453; called by muse, mutect2, varscan2
- FRMD7 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100048654; called by muse, mutect2, varscan2
- FRMPD1 | c.2557C>A p.P853T | Missense Mutation (SNP) | VAF 58/65 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100899259; called by muse, mutect2, varscan2
- FRMPD3 | c.4546G>A p.D1516N | Missense Mutation (SNP) | VAF 70/79 reads (89%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV52186951, COSV99345588; called by muse, mutect2, varscan2
- FRYL | c.5939C>T p.S1980F | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV99975616; called by muse, mutect2, varscan2
- FTCD | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs537044268, COSV99384647; called by muse, mutect2, varscan2
- FUT5 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.641); catalogued as COSV53135181; called by muse, mutect2, varscan2
- FUT5 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99398500; called by muse, mutect2, varscan2
- FYB2 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1464948767, COSV100599172; called by muse, mutect2, varscan2
- FZD2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867681109, COSV59528501; called by muse, mutect2, varscan2
- FZD4 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 89/189 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776026462, COSV72294363; called by muse, mutect2, varscan2
- FZD7 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 132/218 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53808842, COSV99636783; called by muse, mutect2, varscan2
- GABBR2 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 59/66 reads (89%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.993); catalogued as rs757532252, COSV52315011, COSV99408906; called by muse, mutect2, varscan2
- GABPB2 | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1183167436, COSV100927185; called by muse, mutect2, varscan2
- GABRA6 | c.564G>A p.W188* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as COSV50877458, COSV50877753; called by muse, mutect2, varscan2
- GABRB2 | c.1228G>A p.E410K (on ENST00000274547; = p.E372K on NM_000813.3) | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as rs148772321, COSV99196631; called by muse, mutect2, varscan2
- GABRE | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 62/64 reads (97%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as COSV100944205, COSV64819519; called by muse, mutect2, varscan2
- GADL1 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.268); catalogued as COSV99243704; called by muse, mutect2, varscan2
- GALNT13 | c.1596G>A p.M532I | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV101222114; called by muse, mutect2, varscan2
- GALNT14 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100204023, COSV100205455; called by muse, mutect2, varscan2
- GALNT14 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100204024; called by muse, mutect2, varscan2
- GALNT17 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs774180231, COSV61149361, COSV61166524; called by muse, mutect2, varscan2
- GALNT6 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV100695283, COSV100695464; called by muse, mutect2, varscan2
- GAREM1 | c.2473T>A p.L825M (on ENST00000269209 / NM_001242409.2; = p.L824M on NM_022751.3) | Missense Mutation (SNP) | VAF 64/71 reads (90%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99330136; called by muse, mutect2, varscan2
- GATM | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383052173, COSV101188093; called by muse, mutect2, varscan2
- GBP5 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as rs1201264136, COSV100599972; called by muse, mutect2, varscan2
- GCFC2 | c.1270C>T p.H424Y | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100319332; called by muse, mutect2, varscan2
- GCKR | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as rs146855458; called by muse, mutect2, varscan2
- GCOM1 | c.675G>A p.M225I | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs771060878, COSV51096822; called by muse, mutect2, varscan2
- GDPGP1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1413454607, COSV100291999; called by muse, mutect2, varscan2
- GFPT1 | c.773G>A p.R258H (on ENST00000357308 / NM_001244710.2; = p.R240H on NM_002056.4) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); catalogued as COSV61949702, COSV61951610; called by muse, mutect2
- GFRAL | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV61229588; called by muse, mutect2, varscan2
- GGA2 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 72/106 reads (68%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.854); catalogued as rs1567363617, COSV59168952; called by muse, mutect2, varscan2
- GGT1 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as rs1271704918, COSV99958508; called by muse, mutect2, varscan2
- GIMAP8 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 111/170 reads (65%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV100217309; called by muse, mutect2, varscan2
- GIMAP8 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.068); catalogued as rs771833252, COSV56231215; called by muse, mutect2, varscan2
- GLDN | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1197412772, COSV100117465; called by muse, mutect2, varscan2
- GLI1 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs758959112, COSV99953638; called by muse, mutect2, varscan2
- GLIS3 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV100172996; called by muse, mutect2, varscan2
- GLP1R | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100952440; called by muse, mutect2, varscan2
- GLYAT | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.3); catalogued as COSV99557090; called by muse, mutect2, varscan2
- GLYCTK | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV99980600; called by muse, mutect2, varscan2
- GMEB1 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99602932; called by muse, mutect2, varscan2
- GOLGA2 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 191/218 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV101425776; called by muse, mutect2, varscan2
- GOLGB1 | c.3179T>A p.I1060N | Missense Mutation (SNP) | VAF 70/118 reads (59%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV100510282; called by muse, mutect2, varscan2
- GOLM1 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs778395865, COSV99974205; called by muse, mutect2, varscan2
- GP2 | c.1148G>C p.G383A (on ENST00000381362 / NM_001007240.3; = p.G380A on NM_001502.4) | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100221227; called by muse, mutect2, varscan2
- GP2 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100221229; called by muse, mutect2, varscan2
- GP6 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV59979540; called by muse, mutect2, varscan2
- GPATCH8 | c.4244C>T p.P1415L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100132423; called by muse, mutect2, varscan2
- GPLD1 | c.2462G>A p.R821K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.352); catalogued as COSV99218683; called by muse, mutect2, varscan2
- GPLD1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV100014949; called by muse, mutect2, varscan2
- GPR137 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.085); catalogued as COSV100463898; called by muse, mutect2, varscan2
- GPR158 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 82/152 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350723305, COSV66274209; called by muse, mutect2, varscan2
- GPR4 | c.174C>A p.N58K | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100546899; called by muse, mutect2, varscan2
- GPRIN2 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1555019281, COSV100966278; called by muse, mutect2, varscan2
- GPX6 | c.543G>A p.W181* | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | catalogued as COSV62657745; called by muse, mutect2, varscan2
- GRIA1 | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99597914; called by muse, mutect2, varscan2
- GRID1 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV100021693, COSV60022029; called by muse, mutect2, varscan2
- GRID2 | c.2204G>A p.G735E | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV56217187; called by muse, mutect2, varscan2
- GRIN2A | c.3947G>A p.R1316K | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100408152; called by muse, mutect2, varscan2
- GRIN2A | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.552); catalogued as COSV58038477, COSV58061066; called by muse, mutect2, varscan2
- GRIN2B | c.4103G>A p.G1368D | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.618); catalogued as COSV101662897; called by muse, mutect2, varscan2
- GRIP1 | c.2456G>A p.G819E (on ENST00000359742 / NM_001379345.1; = p.G767E on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV54021877; called by muse, mutect2, varscan2
- GRM3 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 77/121 reads (64%) | SIFT tolerated (0.26); PolyPhen benign (0.095); catalogued as COSV64471242, COSV64471575; called by muse, varscan2
- GRM3 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.756); catalogued as COSV64469393; called by muse, varscan2
- GRM3 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0.155); catalogued as COSV64471988; called by muse, mutect2, varscan2
- GRM3 | c.2570C>T p.S857F | Missense Mutation (SNP) | VAF 110/311 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100862061; called by muse, mutect2, varscan2
- GRM7 | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV100735522; called by muse, mutect2, varscan2
- GRM7 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 58/97 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs781373607, COSV63138807; called by muse, mutect2, varscan2
- GRXCR2 | c.55G>C p.V19L | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100939968; called by muse, mutect2, varscan2
- GTF2H5 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV101659561; called by muse, mutect2, varscan2
- GTF3C1 | c.5558C>T p.P1853L | Missense Mutation (SNP) | VAF 57/77 reads (74%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1412071305, COSV100648917; called by muse, mutect2, varscan2
- GZMK | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as rs867228118, COSV50247989, COSV99140830; called by muse, mutect2, varscan2
- HCAR1 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 154/230 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs373721601; called by muse, mutect2, varscan2
- HCN1 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs868143772, COSV100298338; called by muse, mutect2, varscan2
- HCRTR2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866684522, COSV63795299; called by muse, mutect2, varscan2
- HCRTR2 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs201301558, COSV63793801, COSV63798056, COSV63799846; called by muse, mutect2, varscan2
- HDAC7 | c.1997C>T p.P666L (on ENST00000427332; = p.P705L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/91 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99315477; called by muse, mutect2, varscan2
- HDAC7 | c.205C>G p.L69V (on ENST00000427332; = p.L108V on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV99315479; called by muse, mutect2, varscan2
- HDAC9 | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV67766950, COSV67785899; called by muse, mutect2, varscan2
- HEATR1 | c.4658C>A p.T1553N | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1447897162, COSV100857369, COSV100857579; called by muse, mutect2, varscan2
- HEATR5B | c.467T>C p.I156T | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.55); catalogued as rs373532513; called by muse, mutect2, varscan2
- HECW1 | c.4606G>A p.G1536R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs777772311, COSV101222758; called by muse, mutect2, varscan2
- HELB | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV56075023; called by muse, mutect2, varscan2
- HEPACAM2 | c.382G>A p.G128R (on ENST00000394468 / NM_001039372.4; = p.G116R on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100506359; called by muse, mutect2, varscan2
- HEYL | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.48); PolyPhen benign (0.297); catalogued as rs778282702, COSV100865265; called by muse, varscan2
- HHIPL2 | c.1018G>T p.G340* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV100596554; called by muse, mutect2, varscan2
- HHLA2 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as rs1272904239, COSV63320800; called by muse, mutect2, varscan2
- HIF3A | c.1139G>A p.S380N (on ENST00000377670 / NM_152795.4; = p.S311N on NM_022462.4) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV99355464; called by muse, mutect2, varscan2
- HIVEP3 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV99911363; called by muse, mutect2, varscan2
- HJV | c.478C>T p.R160C (on ENST00000336751 / NM_213653.4; = p.R47C on NM_145277.5) | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV100382181; called by muse, mutect2, varscan2
- HKDC1 | c.2607-1G>T p.X869_splice | Splice Site (SNP) | VAF 67/130 reads (52%) | catalogued as rs1466267127, COSV100664348; called by muse, mutect2, varscan2
- HLA-DRA | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 111/153 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770825671, COSV100895037; called by muse, mutect2, varscan2
- HNRNPA3 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.952); catalogued as COSV101182826; called by muse, mutect2, varscan2
- HNRNPM | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1214434398, COSV99725174; called by muse, mutect2, varscan2
- HPS3 | c.1655A>G p.K552R | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99937098; called by muse, mutect2, varscan2
- HS3ST4 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs749218404, COSV58830788; called by muse, mutect2, varscan2
- HS3ST5 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs775679934, COSV57140921; called by muse, mutect2, varscan2
- HSD3B2 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 66/103 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV101027407; called by muse, mutect2, varscan2
- HSPG2 | c.2921G>A p.G974E | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101020360; called by muse, mutect2, varscan2
- HSPG2 | c.2920G>A p.G974R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs752060920, COSV101020560, COSV65978770; called by muse, mutect2, varscan2
- HTR4 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100087136; called by muse, mutect2, varscan2
- HTT | c.5485C>T p.H1829Y | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.977); catalogued as COSV100750357; called by muse, mutect2, varscan2
- HUNK | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV99527964; called by muse, mutect2, varscan2
- HUNK | c.898C>T p.L300F | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as rs1255409761, COSV99527966; called by muse, mutect2, varscan2
- HUWE1 | c.8992G>A p.A2998T | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99470506; called by muse, mutect2, varscan2
- HYDIN | c.9082C>T p.Q3028* | Nonsense Mutation (SNP) | VAF 33/48 reads (69%) | catalogued as rs1429779649, COSV99991850; called by muse, mutect2, varscan2
- HYDIN | c.5671C>T p.P1891S | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs889143307; called by muse, mutect2, varscan2
- HYDIN | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs140028548; called by muse, mutect2, varscan2
- HYDIN | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99861835; called by mutect2, varscan2
- IARS1 | c.477C>T p.V159= | Splice Region (SNP) | VAF 32/36 reads (89%) | catalogued as COSV100986771; called by muse, mutect2, varscan2
- IDO1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.904); catalogued as COSV53714036; called by muse, mutect2
- IDO1 | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV99503139; called by muse, mutect2, varscan2
- IFIT1B | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 52/158 reads (33%) | catalogued as rs373382761, COSV65663300; called by muse, mutect2, varscan2
- IFNGR1 | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1174089963, COSV100880398; called by muse, mutect2, varscan2
- IGDCC4 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT tolerated (0.67); PolyPhen benign (0.281); catalogued as rs750478576, COSV100732669; called by muse, mutect2, varscan2
- IGHG3 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 82/148 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs374103999; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.8G>A p.W3* | Nonsense Mutation (SNP) | VAF 47/238 reads (20%) | catalogued as rs757552862; called by muse, varscan2
- IGHV4-34 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 96/162 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs587753421; called by muse, mutect2, varscan2
- IGSF10 | c.5272C>T p.H1758Y | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV56791613; called by muse, mutect2, varscan2
- IKZF2 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100563149; called by muse, mutect2, varscan2
- IL17REL | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as COSV100377255; called by muse, mutect2, varscan2
- IL25 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs369895955; called by muse, mutect2, varscan2
- IL2RA | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99906457; called by muse, mutect2, varscan2
- IL36B | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.389); catalogued as COSV52088962; called by muse, mutect2, varscan2
- IL9R | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.42); catalogued as COSV99729171; called by muse, mutect2, varscan2
- IMMP2L | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs866098474, COSV100067357, COSV104405112; called by muse, mutect2, varscan2
- ING5 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs185566428, COSV100545903; called by muse, mutect2, varscan2
- INSRR | c.3271G>A p.E1091K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs145039687, COSV63871389; called by muse, mutect2, varscan2
- IPCEF1 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99499024; called by muse, mutect2, varscan2
- IQCA1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99608471; called by muse, mutect2, varscan2
- IQGAP3 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100752042; called by muse, mutect2, varscan2
- IRS1 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs375677810; called by muse, mutect2, varscan2
- IRS1 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.549); catalogued as COSV100523956; called by muse, mutect2, varscan2
- IRS4 | c.2369C>T p.P790L | Missense Mutation (SNP) | VAF 181/208 reads (87%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as COSV100929409; called by muse, mutect2, varscan2
- IRX4 | c.1247T>A p.V416E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as rs764987230, COSV99180764; called by muse, varscan2
- ISG15 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.54); PolyPhen benign (0.177); catalogued as COSV101046053; called by muse, mutect2, varscan2
- ITGA4 | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.082); catalogued as COSV101223066; called by muse, mutect2, varscan2
- ITGA8 | c.1108C>T p.L370F | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV65227968; called by muse, mutect2, varscan2
- ITGA9 | c.651G>A p.W217* | Nonsense Mutation (SNP) | VAF 30/85 reads (35%) | catalogued as COSV99291498; called by muse, mutect2, varscan2
- ITGB6 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99324077; called by muse, mutect2, varscan2
- ITIH2 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs377214728; called by muse, mutect2, varscan2
- ITK | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs372181411; called by muse, mutect2, varscan2
- ITPK1 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as rs916309062, COSV99968165; called by muse, mutect2, varscan2
- JAKMIP3 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs184195749; called by muse, varscan2
- JCAD | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1234546117, COSV100948042; called by muse, mutect2, varscan2
- JCAD | c.1065C>A p.N355K | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs374857313, COSV100948043; called by muse, mutect2, varscan2
- JPH4 | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs752956989, COSV100436519; called by muse, mutect2, varscan2
- KALRN | c.6964G>A p.G2322R (on ENST00000360013 / NM_001024660.4; = p.G625R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99360946; called by muse, mutect2, varscan2
- KANK4 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as rs149755007, COSV62985214; called by muse, mutect2, varscan2
- KAT14 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 190/407 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100890025; called by muse, mutect2, varscan2
- KCMF1 | c.886T>C p.L296= | Splice Region (SNP) | VAF 5/16 reads (31%) | catalogued as rs764542476, COSV101301223; called by muse, mutect2, varscan2
- KCNH5 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV59751489; called by muse, mutect2, varscan2
- KCNH6 | c.1424C>T p.T475I | Missense Mutation (SNP) | VAF 60/86 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs764804361, COSV100120764; called by muse, mutect2, varscan2
- KCNH7 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as COSV100033883; called by muse, mutect2, varscan2
- KCNJ11 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60594178; called by muse, mutect2, varscan2
- KCNK1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV100785657; called by muse, mutect2, varscan2
- KCNK13 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 17/88 reads (19%) | catalogued as COSV99965482; called by muse, mutect2, varscan2
- KCNQ5 | c.1928C>T p.S643L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.719); catalogued as COSV100571148, COSV59656734; called by muse, mutect2, varscan2
- KCNT2 | c.2782-1G>A p.X928_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | catalogued as COSV54065672; called by muse, mutect2, varscan2
- KCNT2 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54089733; called by muse, varscan2
- KCTD2 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1319572990, COSV59368423; called by muse, mutect2, varscan2
- KCTD5 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1410240822, COSV100069444; called by muse, mutect2, varscan2
- KHDRBS2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs1485369570, COSV99830699; called by muse, mutect2
- KIAA1549 | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as rs761475697, COSV99649692; called by muse, mutect2, varscan2
- KIAA1549L | c.860T>A p.F287Y (on ENST00000321505; = p.F584Y on NM_012194.3) | Missense Mutation (SNP) | VAF 89/158 reads (56%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV99682560; called by muse, mutect2, varscan2
- KIAA1549L | c.1027C>T p.P343S (on ENST00000321505; = p.P640S on NM_012194.3) | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV99682561; called by muse, mutect2, varscan2
- KIF18B | c.2114C>T p.A705V (on ENST00000593135 / NM_001265577.2; = p.A717V on NM_001264573.2) | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV100191737; called by muse, mutect2, varscan2
- KIF20B | c.1636C>T p.Q546* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV53308758, COSV99589427; called by muse, mutect2, varscan2
- KIF26B | c.530G>A p.W177* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as COSV101313744; called by muse, mutect2, varscan2
- KIF26B | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as rs1223391457, COSV101313745; called by muse, mutect2
- KIF5C | c.2797G>A p.A933T | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV101276091; called by muse, mutect2, varscan2
- KIFC1 | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100995969; called by muse, mutect2, varscan2
- KIRREL1 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 83/218 reads (38%) | catalogued as COSV100779214; called by muse, mutect2, varscan2
- KL | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs867359183, COSV66307933; called by muse, mutect2, varscan2
- KLHL1 | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV100916948, COSV64767242; called by muse, mutect2
- KLHL13 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 75/88 reads (85%) | SIFT tolerated (0.18); PolyPhen benign (0.2); catalogued as rs267606325, COSV53248919; called by muse, mutect2, varscan2
- KLHL14 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 110/133 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs750963874, COSV100808595; called by muse, mutect2, varscan2
- KLHL4 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 49/54 reads (91%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV100909063, COSV64146097; called by muse, mutect2, varscan2
- KMT2B | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.383); catalogued as rs865950924, COSV99385846; called by muse, mutect2, varscan2
- KMT2E | c.1742T>C p.M581T | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99995734; called by muse, mutect2, varscan2
- KNL1 | c.4942G>T p.E1648* (on ENST00000346991 / NM_170589.5; = p.E1622* on NM_144508.5) | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100705862; called by muse, mutect2, varscan2
- KNL1 | c.5198C>T p.P1733L (on ENST00000346991 / NM_170589.5; = p.P1707L on NM_144508.5) | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV100705864; called by muse, mutect2, varscan2
- KRT3 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs751579090, COSV58814476; called by muse, mutect2, varscan2
- KRT3 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 143/214 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100526873; called by muse, mutect2, varscan2
- KRT5 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM981146, COSV99357771; called by muse, mutect2, varscan2
- KRT76 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 88/156 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100195849; called by muse, mutect2, varscan2
- KRT78 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV58852239, COSV58852742; called by muse, mutect2, varscan2
- KRT9 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs1299017865, COSV55854802; called by muse, mutect2, varscan2
- KRT9 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.916); catalogued as COSV99878988, COSV99879302; called by muse, mutect2, varscan2
- KSR2 | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100194113; called by muse, mutect2
- L1TD1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV100776528; called by muse, mutect2
- LAD1 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1208779214, COSV100943772; called by muse, mutect2
- LAD1 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100943773; called by muse, mutect2
- LAD1 | c.637T>A p.S213T | Missense Mutation (SNP) | VAF 70/306 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as COSV100943774; called by muse, mutect2, varscan2
- LAIR2 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 85/132 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs1360950295, COSV56623497; called by muse, mutect2, varscan2
- LAMA1 | c.4766G>A p.G1589E | Missense Mutation (SNP) | VAF 112/128 reads (88%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.969); catalogued as COSV101054848; called by muse, mutect2, varscan2
- LAMA2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1231305572, COSV101369907; called by muse, mutect2, varscan2
- LAMA2 | c.5290G>A p.E1764K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1429579718, COSV70338364, COSV70355322; called by muse, mutect2, varscan2
- LAMA5 | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.205); catalogued as rs779693522, COSV99437804; called by muse, mutect2, varscan2
- LAMB4 | c.1766A>G p.N589S | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV99222582; called by muse, mutect2, varscan2
- LAPTM5 | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV99612166; called by muse, mutect2, varscan2
- LARP6 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100150662; called by muse, mutect2, varscan2
- LATS1 | c.2472T>G p.F824L | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99485185; called by muse, mutect2, varscan2
- LATS2 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1298390454, COSV101231449; called by muse, mutect2, varscan2
- LCOR | c.4557G>T p.K1519N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV99616554; called by muse, mutect2, varscan2
- LDHC | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1411046576, COSV99772276; called by muse, mutect2, varscan2
- LEPR | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60757682; called by muse, mutect2, varscan2
- LGI1 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101004348; called by muse, mutect2, varscan2
- LGR6 | c.1841C>T p.S614F (on ENST00000367278 / NM_001017403.1; = p.S562F on NM_021636.3) | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.864); catalogued as COSV55153173; called by muse, mutect2, varscan2
- LHCGR | c.1394G>A p.W465* | Nonsense Mutation (SNP) | VAF 48/80 reads (60%) | catalogued as COSV99683100; called by muse, mutect2, varscan2
- LIPI | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs867097666, COSV60709067; called by muse, mutect2, varscan2
- LIPJ | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100905860, COSV100905863; called by muse, mutect2, varscan2
- LLGL1 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100375048; called by muse, mutect2, varscan2
- LLGL1 | c.2297G>A p.G766D | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV100375050; called by muse, mutect2, varscan2
- LMF1 | c.624G>A p.W208* | Nonsense Mutation (SNP) | VAF 32/39 reads (82%) | catalogued as COSV51903270; called by muse, mutect2, varscan2
- LMOD2 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs779763482, COSV101505404, COSV101505442; called by muse, varscan2
- LMOD2 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV71755561; called by muse, mutect2, varscan2
- LMTK2 | c.583C>G p.P195A | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99805919; called by muse, mutect2
- LPA | c.3962A>G p.N1321S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764610863, COSV100305994; called by muse, mutect2, varscan2
- LPA | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 21/503 reads (4%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as rs1301373299; called by muse, mutect2
- LRAT | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV100311994; called by muse, mutect2, varscan2
- LRP1B | c.12700G>A p.D4234N | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as rs867914094, COSV67244438; called by muse, mutect2, varscan2
- LRP1B | c.10814G>A p.G3605E | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.691); catalogued as COSV67194468; called by muse, mutect2, varscan2
- LRP1B | c.7523C>T p.S2508F | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1393251553, COSV67193597; called by muse, mutect2, varscan2
- LRP1B | c.6491C>T p.S2164F | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV67248683; called by muse, mutect2, varscan2
- LRP1B | c.6423G>T p.E2141D | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs753290244, COSV101251794, COSV67232459; called by muse, mutect2, varscan2
- LRP2 | c.9125G>A p.G3042E | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); catalogued as COSV99786353; called by muse, mutect2, varscan2
- LRP5 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 47/71 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs145897519, COSV53715398; called by muse, mutect2, varscan2
- LRRC18 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as COSV53285590; called by muse, mutect2, varscan2
- LRRC27 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59809981; called by muse, mutect2, varscan2
- LRRC28 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs757188580, COSV57336133; called by muse, mutect2, varscan2
- LRRC37A2 | c.3974C>T p.P1325L | Missense Mutation (SNP) | VAF 95/301 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs1230687792, COSV100238596; called by muse, mutect2, varscan2
- LRRC66 | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100602816; called by muse, mutect2, varscan2
- LRRFIP1 | c.2032G>A p.D678N (on ENST00000392000 / NM_001137552.2; = p.D654N on NM_004735.4) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99790317; called by muse, mutect2, varscan2
- LSP1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV100288849; called by muse, mutect2, varscan2
- LTBP2 | c.4777G>A p.D1593N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0.356); catalogued as COSV99999604; called by muse, mutect2, varscan2
- LTBP2 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.198); catalogued as rs779060400, COSV99999608; called by muse, mutect2, varscan2
- LUM | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 111/155 reads (72%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as COSV57127963; called by muse, mutect2, varscan2
- LYN | c.1051A>T p.I351F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV101319561; called by muse, mutect2, varscan2
- MACF1 | c.8473C>T p.Q2825* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99240951; called by muse, mutect2, varscan2
- MAGEB18 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100305278; called by muse, mutect2, varscan2
- MAGEC2 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 106/125 reads (85%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV99909373; called by muse, mutect2, varscan2
- MAGI1 | c.4019G>A p.R1340K | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as rs1294175747, COSV100439203; called by muse, mutect2, varscan2
- MALL | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757582506, COSV55600831; called by muse, mutect2, varscan2
- MAN1A1 | c.1153A>T p.K385* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV100870570, COSV100870724; called by muse, mutect2, varscan2
- MAN1B1 | c.1735C>T p.Q579* | Nonsense Mutation (SNP) | VAF 84/98 reads (86%) | catalogued as COSV100857283; called by muse, mutect2, varscan2
- MAN2B1 | c.864C>A p.N288K | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs146909343, COSV99666612; called by muse, mutect2, varscan2
- MAP10 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.346); catalogued as rs934243635, COSV69362955; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100186510; called by muse, mutect2, varscan2
- MAP3K11 | c.2369C>T p.P790L | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV100442014; called by muse, mutect2, varscan2
- MAPK8IP1 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs777890773, COSV99571072; called by muse, mutect2, varscan2
- MAPKBP1 | c.953G>A p.R318Q (on ENST00000456763 / NM_001128608.2; = p.R312Q on NM_014994.3) | Missense Mutation (SNP) | VAF 74/86 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs150872011; called by muse, mutect2
- MARCHF10 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 67/93 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60888759; called by muse, mutect2, varscan2
- MARCO | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV100503161; called by muse, mutect2, varscan2
- MARCO | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.307); catalogued as rs1448907863, COSV100503163; called by muse, mutect2, varscan2
- MASP1 | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs1062049; called by muse, mutect2, varscan2
- MAST3 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 39/186 reads (21%) | catalogued as COSV99444294; called by muse, mutect2, varscan2
- MAST4 | c.1207G>T p.V403F (on ENST00000403625 / NM_001164664.2; = p.V214F on NM_015183.3) | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99842694; called by muse, mutect2, varscan2
- MAT1A | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV64744781, COSV64746056; called by muse, mutect2, varscan2
- MATR3 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100735097; called by muse, mutect2, varscan2
- MBD5 | c.2308C>T p.H770Y | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs778118780, COSV68695853; called by muse, mutect2, varscan2
- MCM3 | c.573C>A p.N191K (on ENST00000229854 / NM_001366374.2; = p.N181K on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.738); catalogued as COSV100008545; called by muse, mutect2, varscan2
- MCPH1 | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100765215; called by muse, mutect2, varscan2
- MDGA1 | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1267043895, COSV99776183; called by muse, mutect2, varscan2
- MEA1 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 180/434 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs766285051, COSV99775581; called by muse, mutect2, varscan2
- MED12 | c.2015C>T p.S672F | Missense Mutation (SNP) | VAF 54/58 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV100375845; called by muse, mutect2, varscan2
- MED15 | c.1730C>T p.S577L (on ENST00000263205 / NM_001003891.3; = p.S537L on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as rs1461282663, COSV53031715; called by muse, mutect2, varscan2
- MEGF10 | c.2012G>A p.G671E | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99174690; called by muse, mutect2, varscan2
- MEP1B | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV99328629; called by muse, mutect2, varscan2
- MEPE | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs868133447, COSV63072516; called by muse, mutect2, varscan2
- METTL16 | c.1138C>A p.H380N | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV99563068; called by muse, mutect2, varscan2
- MFSD2B | c.206T>G p.L69R | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767978286, COSV100600963; called by muse, mutect2, varscan2
1,565 further variants in this file (795 protein-altering or splice-affecting, 715 silent, 55 other) are not listed here.
